Gene-level copy-number profile of tumor specimen TCGA-04-1365-01A from TCGA case TCGA-04-1365, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-04-1365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1461657f-a324-4423-8eea-8d284dde4139.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1365-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4fee2566-67f0-48de-ad08-4d8bbd39b2c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 15,806; copy number 2: 39,249; copy number 3: 2,985; copy number 4: 1,660; copy number 5: 47; copy number 6: 24; copy number 7: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1365-01): tumor purity 0.82, ploidy 1.89, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:406,428–545,781, 4 genes (within-gene range 0–1): FBXO25, AC083964.1, AC083964.2, TDRP.
- chr10:87,994,618–88,049,823, 2 genes: AC063965.1, MED6P1.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,389,567–49,209,779, 14 genes (within-gene range 0–1): LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2.
- chr16:86,899,356–86,961,268, 2 genes (within-gene range 0–1): AC093519.2, AC093519.1.
- chr17:18,697,998–18,842,364, 6 genes: TRIM16L, AC026271.3, FBXW10, TVP23B, AC107982.3, AC107982.1.
- chr17:18,840,618–18,861,466, 2 genes: RN7SL627P, AC107982.2.
- chr17:60,810,165–60,811,462, 1 gene: KRT18P61.
- chr18:77,180,106–77,277,900, 2 genes: AC100863.1, GALR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:60,629,662–60,967,775, 9 genes, copy number 7: AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2.
- chr11:72,285,495–72,434,680, 1 gene, copy number 6 (within-gene range 4–6): CLPB.
- chr11:72,351,347–73,761,137, 46 genes, copy number 5–6: AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1.
- chr19:9,751,993–9,793,180, 1 gene, copy number 5 (within-gene range 2–5): ZNF846.
- chr19:9,774,497–10,119,918, 23 genes, copy number 5: UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G.

Autosomal genes at a single copy (total copy number 1): 15,806. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
